CPTAC case C3N-02451 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/235e3ff0-5389-48c6-8d25-7e8bc9ee14b6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 78.2 years (28,546 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 2,125 days (5.8 years); Progression or recurrence: no; Days to last follow up: 2,125 days (5.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 18; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 627 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 1,041 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,386 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,386 days (3.8 years); Disease response: Complete Response.
- Days to follow up: 1,735 days (4.8 years); Disease response: Tumor Free.
- Days to follow up: 2,125 days (5.8 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 73.48 kg; Height: 162.56 cm; BMI: 27.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Cigarettes per day: 10; Tobacco smoking onset year: 1955; Tobacco smoking quit year: 1975; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02451-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 301 days; Initial weight: 128 mg; Time between excision and freezing: 38 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02451-23: Section location: Right Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 3.
- Sample C3N-02451-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 301 days; Initial weight: 127 mg; Time between excision and freezing: 38 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02451-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 301 days; Method of sample procurement: Blood Draw.
